Somatic mutation profile of tumor specimen TCGA-B2-5641-01A (aliquot TCGA-B2-5641-01A-01D-1534-10) from TCGA case TCGA-B2-5641, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 79.3 years (28,953 days).
Specimen TCGA-B2-5641-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e7595c3-0b0c-4115-b004-4ef3dd016944.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5641-10A (Blood Derived Normal), aliquot TCGA-B2-5641-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2a76db7-38e9-452c-8fb4-9e7167476951

The open-access MAF lists 74 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 13, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMDEC1 | c.67T>C p.W23R | Missense Mutation (SNP) | VAF 83/381 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs1038227765, COSV56475470, COSV56475935; called by muse, mutect2, varscan2
- ANKRD30A | c.629T>G p.M210R (on ENST00000611781; = p.M154R on NM_052997.2) | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV64613700; called by muse, mutect2, varscan2
- BCL9L | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV58314299; called by muse, mutect2, varscan2
- BRCA2 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 103/512 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66456484; called by muse, mutect2, varscan2
- CACNA1D | c.1802A>C p.E601A (on ENST00000350061 / NM_001128840.3; = p.E621A on NM_000720.4) | Missense Mutation (SNP) | VAF 29/602 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55453100; called by muse, mutect2
- CACNA1S | c.3331G>A p.V1111M | Missense Mutation (SNP) | VAF 82/427 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs200558548, COSV62941027; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CCDC90B | c.395G>C p.S132T | Missense Mutation (SNP) | VAF 35/842 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV52624375; called by muse, mutect2
- CENPC | c.2320C>G p.P774A | Missense Mutation (SNP) | VAF 195/967 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs762694889, COSV56624300; called by muse, mutect2, varscan2
- CLDN12 | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55305950; called by muse, mutect2, varscan2
- DAXX | c.1370A>T p.E457V | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV56470697; called by muse, mutect2, varscan2
- DDX4 | c.1178G>A p.C393Y | Missense Mutation (SNP) | VAF 82/523 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61755717; called by muse, mutect2, varscan2
- FBXO41 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs1338379217, COSV54586196; called by muse, mutect2, varscan2
- FUS | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV54215643; called by muse, mutect2, varscan2
- GNPTAB | c.2115del p.D706Tfs*4 | Frame Shift Del (DEL) | VAF 44/232 reads (19%) | catalogued as COSV68450021; called by mutect2, pindel, varscan2
- KIAA0586 | c.3340T>G p.F1114V (on ENST00000619416 / NM_001244190.2; = p.F1053V on NM_014749.5) | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54177891; called by muse, mutect2
- KIAA1109 | c.2954C>A p.S985* | Nonsense Mutation (SNP) | VAF 194/1121 reads (17%) | catalogued as COSV52679699, COSV52688368; called by muse, mutect2
- KIF20A | c.1093A>G p.N365D | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50154809; called by muse, mutect2, varscan2
- MACROD2 | c.1145-1G>C p.X382_splice (on ENST00000642719; = p.X354_splice on NM_080676.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 135/764 reads (18%) | catalogued as COSV53946838, COSV54005874, COSV99428277; called by muse, mutect2, varscan2
- MAP3K2 | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV61294997, COSV61296134; called by muse, mutect2, varscan2
- MED13 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 84/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1305895746, COSV67264591; called by muse, mutect2, varscan2
- MNS1 | c.996T>G p.Y332* | Nonsense Mutation (SNP) | VAF 253/1269 reads (20%) | catalogued as COSV53069099; called by muse, mutect2, varscan2
- MYO5A | c.3587T>G p.I1196S | Missense Mutation (SNP) | VAF 140/629 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV62561812; called by muse, mutect2, varscan2
- OR6A2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs2741745, COSV60264736; called by muse, mutect2, varscan2
- PCDHB8 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.05); catalogued as rs782643110, COSV50762098; called by muse, mutect2
- PDE8A | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 46/1082 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs559637860, COSV59638192; called by muse, mutect2
- PGM2 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 108/506 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs767958471, COSV67939116; called by muse, mutect2, varscan2
- PHF8 | c.536C>A p.T179N (on ENST00000357988 / NM_001184896.1; = p.T143N on NM_015107.3) | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV57678366, COSV57680030; called by muse, mutect2, varscan2
- PPFIA3 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV61952749; called by muse, mutect2, varscan2
- PROX2 | c.1286T>G p.L429R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV71520093; called by muse, mutect2
- PSAP | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as CM052356, COSV56472432; called by muse, mutect2
- PSD3 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 138/640 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV54074335; called by muse, mutect2, varscan2
- PUS7 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 115/585 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV62677221; called by muse, mutect2, varscan2
- SCN7A | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as COSV101313076, COSV69272709; called by muse, mutect2, varscan2
- SLC12A7 | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1417395988, COSV53758888; called by muse, mutect2
- SLK | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59826516; called by muse, mutect2, varscan2
- SNX25 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV53015817; called by muse, mutect2, varscan2
- SPRED2 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62693710; called by muse, mutect2, varscan2
- SYDE1 | c.1603C>A p.H535N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54620604; called by muse, mutect2, varscan2
- TEK | c.1932C>G p.N644K | Missense Mutation (SNP) | VAF 55/517 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV66230018; called by muse, mutect2, varscan2
- TIAM1 | c.492C>G p.S164R | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV54558669; called by muse, mutect2
- TOM1L2 | c.53A>T p.E18V | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58887045; called by muse, mutect2, varscan2
- TTI1 | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.54); catalogued as COSV65062220; called by muse, mutect2, varscan2
- TTN | c.66768T>G p.Y22256* (on ENST00000591111; = p.Y14832* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 32/165 reads (19%) | catalogued as COSV60153395; called by muse, mutect2, varscan2
- VWA8 | c.716T>C p.I239T | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55699291; called by muse, mutect2, varscan2
- XKR4 | c.1271G>T p.C424F | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59300616; called by muse, mutect2, varscan2
- YME1L1 | c.967G>C p.G323R (on ENST00000326799 / NM_139312.3; = p.G266R on NM_014263.4) | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV58760243; called by muse, mutect2, varscan2
- ZNF180 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1374552059, COSV55422094; called by muse, mutect2, varscan2
- ZNF714 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52513107; called by muse, mutect2, varscan2
- ABCA1 | c.1595_1602del p.F532Wfs*13 | Frame Shift Del (DEL) | VAF 31/286 reads (11%) | called by mutect2, pindel
- CADPS2 | c.1886del p.G629Vfs*31 | Frame Shift Del (DEL) | VAF 94/390 reads (24%) | called by mutect2, pindel, varscan2
- DNAJB6 | c.269_270insAG p.F91Afs*78 | Frame Shift Ins (INS) | VAF 131/684 reads (19%) | called by mutect2, pindel, varscan2
- FBN2 | c.5066del p.I1689Tfs*47 | Frame Shift Del (DEL) | VAF 37/165 reads (22%) | called by mutect2, pindel, varscan2
- KDM5C | c.365_371del p.E122Vfs*14 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by pindel, varscan2
- MRC1 | c.3793C>G p.R1265G | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- RTTN | c.306_309delinsA p.A103del | In Frame Del (DEL) | VAF 50/165 reads (30%) | called by pindel, varscan2*
- SNW1 | c.1358dup p.N453Kfs*9 | Frame Shift Ins (INS) | VAF 37/362 reads (10%) | called by mutect2, pindel, varscan2
- SPPL3 | c.965dup p.Y322* | Nonsense Mutation (INS) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- TRDC | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF84 | c.2170T>A p.S724T | Missense Mutation (SNP) | VAF 49/1018 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2
- CYB5A | c.138T>C p.G46= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV55022300; called by muse, mutect2, varscan2
- DNAJC14 | c.1593A>G p.A531= | Silent (SNP) | VAF 51/241 reads (21%) | catalogued as COSV54478741; called by muse, mutect2, varscan2
- EIF4G3 | c.1620A>G p.V540= | Silent (SNP) | VAF 106/533 reads (20%) | catalogued as COSV51686250; called by muse, mutect2, varscan2
- FNIP2 | c.1785G>C p.P595= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV52441582; called by muse, mutect2, varscan2
- FUS | c.135G>A p.T45= | Silent (SNP) | VAF 45/308 reads (15%) | catalogued as COSV54218095; called by muse, mutect2, varscan2
- IGSF1 | c.2805G>A p.E935= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1236836154, COSV63838326; called by muse, mutect2, varscan2
- KATNB1 | c.615C>T p.A205= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs781986158, COSV65560775; called by muse, mutect2, varscan2
- KDM5C | c.357G>C p.V119= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV62891188; called by muse, varscan2
- KIAA1109 | c.2952T>C p.T984= | Silent (SNP) | VAF 192/1101 reads (17%) | catalogued as COSV52679689, COSV99169633; called by muse, mutect2
- LBP | c.189C>T p.T63= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs751352956, COSV54141196; called by muse, mutect2
- OR9K2 | c.54A>G p.Q18= | Silent (SNP) | VAF 80/848 reads (9%) | catalogued as COSV59532383; called by muse, mutect2
- RESF1 | c.516T>C p.N172= | Silent (SNP) | VAF 58/242 reads (24%) | catalogued as COSV57023331; called by muse, mutect2, varscan2
- SPNS3 | c.1356C>T p.C452= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV61070687; called by muse, mutect2, varscan2
- GNG2 | c.-2C>T | 5'UTR (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- UPB1 | c.364+144G>A | Intron (SNP) | VAF 22/102 reads (22%) | catalogued as COSV100387097; called by muse, mutect2, varscan2
